Surgical pathology report (de-identified scan), TCGA case TCGA-61-1721, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1721-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: RIGHT ADNEXA, RIGHT SALPINGO-OOPHORECTOMY (61 GRAMS) –

- A. PAPILLARY SEROUS CARCINOMA OF THE OVARY, LOW GRADE, WITH PSAMMOMA BODIES / MICROPAPILLARY GROWTH PATTERN (see comment).
- B. LARGEST FOCUS MEASURES 0.9 CM.
- C. SURFACE OF OVARY IS INVOLVED BY CARCINOMA.
- D. LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED.
- E. UNINVOLVED OVARY SHOWS EPITHELIAL INCLUSION CYSTS AND PHYSIOLOGIC CHANGES.
- F. CARCINOMA INVOLVES PARATUBAL TISSUE AND EXTENDS INTO THE WALL AND STROMA OF THE FALLOPIAN TUBE.
- G. BENIGN PARATUBAL CYST.

PART 2: ROUND LIGAMENT, BIOPSY – PAPILLARY SEROUS CARCINOMA.

PART 3: LEFT ADNEXA, LEFT SALPINGO-OOPHORECTOMY (20.3 GRAMS) –

- A. PAPILLARY SEROUS CARCINOMA OF THE OVARY, LOW GRADE, WITH PSAMMOMA BODIES / MICROPAPILLARY GROWTH PATTERN (see comment).
- B. LARGEST FOCUS MEASURES 1.7 CM.
- C. SURFACE OF OVARY IS INVOLVED BY CARCINOMA.
- D. UNINVOLVED OVARY SHOWS EPITHELIAL INCLUSION CYSTS AND PHYSIOLOGIC CHANGES.
- E. CARCINOMA INVOLVES PARATUBAL TISSUE AND EXTENDS INTO THE WALL OF THE FALLOPIAN TUBE.
- F. FALLOPIAN TUBE WITH WALTHARD REST.

PART 4: VAGINA, APEX, TUMOR –

- A. PAPILLARY SEROUS CARCINOMA INVOLVING SUBMUCOSAL TISSUE.
- B. BENIGN VAGINAL MUCOSA.

PART 5: RECTUM, RECTAL TUMOR CAPSULE, BIOPSY – MINUTE FOCUS OF PAPILLARY SEROUS CARCINOMA (0.05 CM).

PART 6: LYMPH NODES, RIGHT PELVIC, BIOPSY –

- A. ONE OF TWO LYMPH NODES POSITIVE FOR METASTATIC PAPILLARY SEROUS CARCINOMA (1/2).
- B. FOCUS MEASURES 0.08 CM.
- C. NO EXTRACAPSULAR EXTENSION IS IDENTIFIED.

[page 2 of 2]
- A. ONE OF TWO LYMPH NODES POSITIVE FOR METASTATIC PAPILLARY SEROUS CARCINOMA (1/2).
B. LARGEST FOCUS MEASURES 0.6 CM.
C. EXTRACAPSULAR EXTENSION IS PRESENT.

PART 8: SIGMOID NODULE, BIOPSY –
PAPILLARY SEROUS CARCINOMA.

PART 9: APPENDIX, APPENDECTOMY –
A. SEROSAL SURFACE IS INVOLVED BY PAPILLARY SEROUS CARCINOMA WITH EXTENSION INTO THE WALL OF THE APPENDIX.
B. TIP SHOWS FIBROUS OBLITERATION WITH FOCAL INVOLVEMENT BY PAPILLARY SEROUS CARCINOMA.

PART 10: LARGE BOWEL MESENTERIC MASS, BIOPSY –
PAPILLARY SEROUS CARCINOMA.

PART 11: OMENTUM, OMENTECTOMY –
PAPILLARY SEROUS CARCINOMA.

PART 12: TRANSVERSE MESENTERIC MASS, BIOPSY –
PAPILLARY SEROUS CARCINOMA.

PART 13: LEFT CUL DE SAC NODULE, BIOPSY –
PAPILLARY SEROUS CARCINOMA.

COMMENT:

The tumor cells demonstrate relatively uniform population with moderate cytologic atypia and up to 5 mitoses per 10 high power fields. Therefore, it is considered a low grade lesion (please refer to the reference articles). Approximately 20% of tumor cells show p53 nuclear positivity, further supporting the low grade nature of the lesion. Modest fibrosis and scattered apoptotic bodies are seen, while no tumor necrosis or foam cell aggregate is identified, indicating minimal response (< 5%) to chemotherapy.

Both ovaries are involved by multiple large nodules of carcinoma. No intraepithelial or invasive carcinoma is identified in the fallopian tubes. Based on the criteria proposed by the [REDACTED], the tumor is considered ovarian primary.

Previous excisional biopsy of the umbilical stalk revealed the involvement of skin
the tumor is regarded as stage IV.

Tissue findings correlate with pelvic wash which is positive for adenocarcinoma /

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	Bilateral Salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 1.7 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Well differentiated (3-5 pts)
ARCHITECTURAL PATTERN:	Papillary (2)
CYTOLOGIC ATYPIA:	Moderate (2)
MITOTIC COUNTS / 10hpf:	0-9 (1)

VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Fallopian Tubes, Omentum, Peritoneal metastasis beyond the pelvis
SURFACE IMPLANT SIZE:	

Source: NCI Genomic Data Commons file 903be6de-ff8e-49c7-848b-c6ac9549385d (TCGA-61-1721.F44D906C-F069-45E6-9CC4-49EB0DA74226.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).